CCDI case PBCCLC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/3db650d0-0d6d-463a-bb8f-f08c49f5f960

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 5.6 years (2,058 days).

Biospecimens (3 samples)
- Sample 0DODMB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DODN2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DODOE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
